Somatic mutation profile of tumor specimen TCGA-4G-AAZR-01A (aliquot TCGA-4G-AAZR-01A-11D-A46P-09) from TCGA case TCGA-4G-AAZR, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 74.3 years (27,151 days).
Specimen TCGA-4G-AAZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a79f8ecc-d508-48e5-8919-d4a44ec87bd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4G-AAZR-11A (Solid Tissue Normal), aliquot TCGA-4G-AAZR-11A-11D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c5fdd72-3106-4fc8-abed-353a8439cf81

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.1675G>A p.G559S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs765994795; ClinVar: likely benign; called by muse, varscan2
- AXIN1 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750117207; called by muse, mutect2, varscan2
- COL5A1 | c.3565G>A p.G1189R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100880052, COSV65666885; called by muse, mutect2, varscan2
- COL6A3 | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs1057518127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCK | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs767152030; called by muse, mutect2, varscan2
- KIRREL1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63285100, COSV63290126; called by muse, mutect2, varscan2
- KMT2C | c.10913C>A p.S3638* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51470831; called by muse, varscan2
- MUC6 | c.6270_6272del p.S2092del | In Frame Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs1564831881; called by pindel, varscan2
- PCK2 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99394651; called by muse, mutect2, varscan2
- RASSF2 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs536661365; called by muse, mutect2, varscan2
- SLIT1 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56596296; called by muse, mutect2, varscan2
- ADAMTS13 | c.2775G>T p.R925S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.114); called by muse, mutect2
- B4GALT2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- G2E3 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC1 | c.3170C>T p.S1057L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NKRF | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- PPIL6 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLF2 | c.2901C>A p.N967K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SREBF2 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SSTR3 | c.1106A>T p.E369V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TGFBR2 | c.946dup p.E316Gfs*49 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- TOP2A | c.167T>G p.L56* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- TRABD2A | c.929A>C p.K310T (on ENST00000409520 / NM_001277053.2; = p.K261T on NM_001080824.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ATP8B2 | c.1413C>T p.F471= (on ENST00000672630; = p.F438= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- CENPB | c.1587C>T p.D529= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs759293866; called by muse, mutect2, varscan2
- COL4A4 | c.4707C>T p.C1569= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs781256511, COSV61631294; called by muse, mutect2, varscan2
- DLX2 | c.135C>T p.S45= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- GPC6 | c.261G>A p.V87= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs199838856; called by muse, mutect2, varscan2
- ITGAD | c.813C>T p.V271= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- NRXN1 | c.2151G>C p.T717= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-177590G>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
